Somatic mutation profile of tumor specimen TCGA-CC-A7IL-01A (aliquot TCGA-CC-A7IL-01A-11D-A33Q-10) from TCGA case TCGA-CC-A7IL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 61.1 years (22,319 days).
Specimen TCGA-CC-A7IL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 525fdae7-b45d-4dc6-b6a7-66eacde6299c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A7IL-10A (Blood Derived Normal), aliquot TCGA-CC-A7IL-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30affad7-49a1-4fd1-91a9-87783bbef0a7

The open-access MAF lists 119 somatic variants for this specimen: 91 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 27, Splice Site 5, Frame Shift Del 4, Nonsense Mutation 4, Splice Region 3, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 39/153 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.643+2T>C p.X215_splice | Splice Site (SNP) | VAF 30/75 reads (40%) | catalogued as COSV55296518; called by muse, mutect2, varscan2
- ALDH16A1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1302672559, COSV53195928; called by muse, mutect2, varscan2
- AMFR | c.1918C>T p.Q640* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs1232716103, COSV51923572; called by muse, mutect2, varscan2
- APPL1 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 136/435 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs1316373298, COSV55700911, COSV55702810; called by muse, mutect2, varscan2
- C14orf93 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1023343891, COSV52985256, COSV52986345; called by muse, mutect2, varscan2
- CACNA1E | c.2649G>T p.W883C | Missense Mutation (SNP) | VAF 121/212 reads (57%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.669); catalogued as COSV62412490; called by muse, mutect2, varscan2
- CHD6 | c.6118C>T p.H2040Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as rs760610864, COSV64693474; called by muse, mutect2, varscan2
- CRISPLD2 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV52282179; called by muse, mutect2, varscan2
- CTCF | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50462921, COSV50501096; called by muse, mutect2, varscan2
- DACH1 | c.2182C>A p.P728T (on ENST00000619232 / NM_001366712.1; = p.P474T on NM_004392.6) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV57515041; called by muse, mutect2, varscan2
- DKK2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53401977; called by muse, mutect2, varscan2
- DMBT1 | c.309G>T p.R103S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV57556356; called by muse, mutect2, varscan2
- DNAJC17 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV53067242; called by muse, mutect2, varscan2
- DNMT3A | c.1610G>T p.C537F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53070868; called by muse, varscan2
- DNMT3A | c.1555-2A>G p.X519_splice | Splice Site (SNP) | VAF 18/32 reads (56%) | catalogued as rs767136883, COSV53053904; called by muse, varscan2
- DQX1 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV66353567; called by muse, mutect2, varscan2
- DYNC1I1 | c.1631A>G p.H544R | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV61468768; called by muse, mutect2, varscan2
- DYRK1A | c.952-2A>T p.X318_splice | Splice Site (SNP) | VAF 30/60 reads (50%) | catalogued as COSV58296400; called by muse, mutect2, varscan2
- ELF3 | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 148/235 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV62839899; called by muse, mutect2, varscan2
- EXO1 | c.2286A>C p.R762S | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV62219145; called by muse, mutect2, varscan2
- F13B | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 117/220 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453580885, COSV66375301; called by muse, mutect2, varscan2
- FBN1 | c.444T>C p.P148= | Splice Region (SNP) | VAF 10/51 reads (20%) | catalogued as COSV57327013; called by muse, mutect2, varscan2
- FILIP1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 39/44 reads (89%) | catalogued as COSV52738109; called by muse, mutect2, varscan2
- FRMPD3 | c.5015G>A p.R1672Q | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs959782725, COSV99346183; called by muse, mutect2, varscan2
- GALNT8 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52900552; called by muse, mutect2, varscan2
- GMPPB | c.771C>T p.D257= | Splice Region (SNP) | VAF 22/63 reads (35%) | catalogued as rs1314961622, COSV57539732; called by muse, mutect2, varscan2
- GNAT3 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 102/316 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV68069852; called by muse, mutect2
- GRIN2A | c.1651+1G>T p.X551_splice | Splice Site (SNP) | VAF 38/130 reads (29%) | catalogued as COSV58051564; called by muse, mutect2, varscan2
- HLA-G | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64406577; called by muse, mutect2, varscan2
- HNRNPK | c.1284A>C p.E428D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV61090712; called by muse, mutect2, varscan2
- HOXC6 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs762610633, COSV54537465, COSV54537935; called by muse, mutect2, varscan2
- IL23R | c.1493T>G p.L498R | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV61375807; called by muse, mutect2, varscan2
- KCNH5 | c.2527G>T p.D843Y | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.195); catalogued as rs1469502913, COSV100526316; called by muse, mutect2, varscan2
- KCNH5 | c.2526G>C p.E842D | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100526318, COSV59752516; called by muse, mutect2, varscan2
- KCNIP2 | c.179C>A p.A60D (on ENST00000356640 / NM_173191.3; = p.A75D on NM_014591.5) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53308262; called by muse, mutect2, varscan2
- KLC4 | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 113/167 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV52438459; called by muse, mutect2, varscan2
- L3MBTL3 | c.557A>C p.D186A | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV62388219; called by muse, mutect2, varscan2
- LRP1B | c.3342G>T p.W1114C | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67260552, COSV67267519; called by muse, mutect2, varscan2
- MAGEL2 | c.3656C>T p.A1219V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs773964986, COSV58568628; called by muse, mutect2, varscan2
- MECOM | c.2882A>G p.H961R (on ENST00000468789 / NM_001105078.4; = p.H1149R on NM_004991.4) | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.829); catalogued as rs779967808, COSV52971770; called by muse, mutect2, varscan2
- MEGF10 | c.2106A>C p.P702= | Splice Region (SNP) | VAF 26/88 reads (30%) | catalogued as COSV57254705; called by muse, mutect2, varscan2
- MICAL2 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 56/79 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV56324637; called by muse, mutect2, varscan2
- MIS18BP1 | c.1867A>G p.I623V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV60372883; called by muse, mutect2, varscan2
- MISP | c.2004G>T p.W668C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53121862; called by muse, mutect2, varscan2
- NAV1 | c.2699G>A p.S900N | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV55223700; called by muse, mutect2, varscan2
- NEPRO | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 305/490 reads (62%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as rs764757072, COSV58724213; called by muse, mutect2, varscan2
- NFKBIA | c.812A>T p.Q271L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53754261; called by muse, mutect2, varscan2
- NPC1L1 | c.2298G>A p.M766I | Missense Mutation (SNP) | VAF 102/175 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56923106; called by muse, mutect2, varscan2
- NR4A3 | c.1253G>C p.R418T | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV58247447; called by muse, mutect2, varscan2
- PCDHB2 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV99165006; called by muse, mutect2, varscan2
- PCDHB2 | c.2011C>G p.P671A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.408); catalogued as COSV99165007; called by muse, mutect2, varscan2
- PCDHGB7 | c.1462T>G p.S488A | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV54008413; called by muse, mutect2, varscan2
- PCGF6 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61495802; called by muse, mutect2, varscan2
- PDE3A | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV62980396; called by muse, mutect2, varscan2
- PDHA2 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.155); catalogued as rs762066606, COSV54778576; called by muse, varscan2
- POLR1A | c.3878T>G p.V1293G | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55697875; called by muse, mutect2, varscan2
- PRF1 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV64615691; called by muse, mutect2, varscan2
- PRKCSH | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV52953357; called by muse, mutect2, varscan2
- PRRX1 | c.106G>T p.V36F | Missense Mutation (SNP) | VAF 193/330 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53415060, COSV53417642; called by muse, mutect2, varscan2
- PTCHD1 | c.1211G>A p.C404Y | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV65062286; called by muse, mutect2, varscan2
- PTN | c.317G>A p.W106* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | catalogued as COSV61968541; called by muse, mutect2, varscan2
- PTPN23 | c.1004-1G>T p.X335_splice | Splice Site (SNP) | VAF 51/85 reads (60%) | catalogued as COSV55547379; called by muse, mutect2, varscan2
- QRFPR | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV57679469; called by muse, mutect2, varscan2
- RAD54B | c.1850A>G p.K617R | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60253887; called by muse, mutect2, varscan2
- RGS3 | c.1061G>A p.C354Y (on ENST00000350696 / NM_001282923.2; = p.C242Y on NM_017790.4) | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58284196; called by muse, mutect2, varscan2
- SAGE1 | c.671C>G p.T224S | Missense Mutation (SNP) | VAF 83/90 reads (92%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as COSV61016593; called by muse, mutect2, varscan2
- SCNN1G | c.1706C>A p.A569D | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); catalogued as COSV55601209; called by muse, mutect2, varscan2
- SEMA3B | c.1703G>C p.G568A | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as rs782201786, COSV57115231; called by muse, mutect2, varscan2
- SH3RF1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52924112, COSV99498710; called by muse, mutect2, varscan2
- SMAD9 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.393); catalogued as COSV63206032, COSV63206055; called by muse, mutect2, varscan2
- TBC1D32 | c.3142C>T p.Q1048* | Nonsense Mutation (SNP) | VAF 75/84 reads (89%) | catalogued as COSV51551446; called by muse, mutect2, varscan2
- TBL1Y | c.742A>C p.T248P | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60733654; called by muse, mutect2, varscan2
- TMC3 | c.1358G>C p.W453S | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV63924205; called by muse, mutect2
- TMC7 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV58586797; called by muse, mutect2, varscan2
- TMIGD3 | c.289G>T p.A97S (on ENST00000369717 / NM_001081976.2; = p.A178S on NM_020683.7) | Missense Mutation (SNP) | VAF 116/254 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.272); catalogued as COSV63163716; called by muse, varscan2
- TRIP11 | c.2111C>A p.S704Y | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV50948117; called by muse, mutect2, varscan2
- UBOX5 | c.398A>G p.H133R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV53908581; called by muse, mutect2, varscan2
- USH2A | c.6348C>G p.H2116Q | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV56417594; called by muse, mutect2, varscan2
- UST | c.673C>A p.R225S | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV66549397, COSV66550910; called by muse, mutect2, varscan2
- ZIM3 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.024); catalogued as COSV54145662; called by muse, mutect2, varscan2
- ZNF23 | c.1076C>G p.T359R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV61841543; called by muse, mutect2, varscan2
- ZNF417 | c.860A>T p.Q287L | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); catalogued as COSV56309621; called by muse, mutect2, varscan2
- ZNF507 | c.1787_1790del p.E596Gfs*12 | Frame Shift Del (DEL) | VAF 31/64 reads (48%) | catalogued as rs1349650607; called by mutect2, pindel, varscan2
- ZNF793 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761931337, COSV71325146; called by muse, mutect2, varscan2
- ANKEF1 | c.1203_1208del p.L402_N403del | In Frame Del (DEL) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- CHRM4 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2
- FCGBP | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IFNA14 | c.523del p.L175Sfs*11 | Frame Shift Del (DEL) | VAF 41/128 reads (32%) | called by mutect2, pindel, varscan2
- LRIG3 | c.423_432del p.K142Sfs*53 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by pindel, varscan2
- TUBB | c.306_327del p.K103Pfs*26 | Frame Shift Del (DEL) | VAF 75/298 reads (25%) | called by mutect2, pindel, varscan2
- AAR2 | c.828G>T p.R276= | Silent (SNP) | VAF 120/175 reads (69%) | catalogued as rs1274453020, COSV57924717; called by muse, mutect2, varscan2
- ACTR1B | c.531T>G p.P177= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV56705199, COSV56705404; called by muse, mutect2, varscan2
- ADGRL4 | c.15G>T p.P5= | Silent (SNP) | VAF 71/161 reads (44%) | catalogued as rs779693719, COSV66064525; called by muse, mutect2, varscan2
- ARSF | c.1029A>G p.T343= | Silent (SNP) | VAF 104/124 reads (84%) | catalogued as rs759666385, COSV63840718; called by muse, mutect2, varscan2
- CES2 | c.1353G>A p.P451= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs768040510, COSV57696744; called by muse, mutect2, varscan2
- CKM | c.882C>A p.G294= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs752715405, COSV53465669, COSV99488397; called by muse, mutect2, varscan2
- CST9 | c.261A>T p.R87= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV65402871; called by muse, mutect2, varscan2
- EIF3H | c.837G>A p.Q279= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV52670999; called by muse, mutect2, varscan2
- EXOSC3 | c.414A>G p.P138= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1445940928, COSV59204154; called by muse, mutect2, varscan2
- GUCY1A2 | c.798G>T p.V266= | Silent (SNP) | VAF 47/67 reads (70%) | catalogued as COSV56497578; called by muse, mutect2, varscan2
- HTRA2 | c.690A>G p.A230= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV51211760; called by muse, mutect2, varscan2
- ITGA4 | c.303C>T p.C101= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs772834562, COSV51998927; called by muse, mutect2, varscan2
- KIF5A | c.2382C>A p.L794= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV54057823, COSV99672783; called by muse, mutect2, varscan2
- LRP12 | c.429G>T p.S143= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV52633245, COSV52633847; called by muse, mutect2, varscan2
- NCEH1 | c.816A>G p.P272= (on ENST00000538775; = p.P232= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as COSV56437377; called by muse, mutect2, varscan2
- NLRP4 | c.1962C>A p.T654= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV56720932, COSV56721017; called by muse, mutect2, varscan2
- NPFFR1 | c.504G>T p.L168= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV53334495; called by muse, mutect2, varscan2
- OR10H1 | c.144C>T p.T48= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs142314142; called by muse, mutect2, varscan2
- OR1E2 | c.942T>A p.I314= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99943426; called by muse, mutect2
- OR2T12 | c.675C>T p.L225= | Silent (SNP) | VAF 176/458 reads (38%) | catalogued as COSV58779061; called by muse, varscan2
- PCDH7 | c.1263G>T p.G421= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as COSV62342474; called by muse, mutect2, varscan2
- PDCD2L | c.9C>G p.A3= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV55826300; called by muse, mutect2, varscan2
- PPM1F | c.1068G>A p.L356= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as rs1444039032, COSV54286143; called by muse, mutect2, varscan2
- TTN | c.38820G>A p.V12940= (on ENST00000591111; = p.V5516= on NM_003319.4) | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV60267125; called by muse, mutect2, varscan2
- VWA3A | c.2184A>G p.V728= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as COSV55394213; called by muse, mutect2, varscan2
- ZFYVE26 | c.903A>G p.L301= | Silent (SNP) | VAF 46/77 reads (60%) | catalogued as COSV61332344; called by muse, mutect2, varscan2
- ZNF184 | c.1578A>G p.Q526= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs371959671; called by muse, mutect2, varscan2
- CTBP2 | c.58+12622C>T | Intron (SNP) | VAF 34/54 reads (63%) | catalogued as COSV58345256; called by muse, mutect2, varscan2
